TCGA case TCGA-CD-8536 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b2f6d8f3-3182-4e5e-be20-8470cfb832c5

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.1; Tissue or organ of origin: Fundus of stomach; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 74.8 years (27,328 days); Year of diagnosis: 2011; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 378 days (1.0 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Cisplatin + Epirubicin; Days to treatment start: 54 days; Days to treatment end: 135 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 3 days; Disease response: Tumor Free.
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CD-8536-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 1.2; Shortest dimension: 0.5.
  Slide TCGA-CD-8536-01A-01-BS1: Section location: Bottom; Percent tumor cells: 78; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 2; Percent stromal cells: 10.
  Slide TCGA-CD-8536-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 65; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CD-8536-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CD-8536-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: No; History reflux disease indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 378 days; disease-specific survival: no event (censored), 378 days; disease-free interval: no event (censored), 378 days; progression-free interval: no event (censored), 378 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CD-8536-01A-11D-2338-01): tumor purity 0.48, ploidy 2.13, whole-genome doublings 0.
